Somatic mutation profile of tumor specimen 0DGBAB from CCDI case PBBSTE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.0 years (5,493 days).
Specimen 0DGBAB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 432059b6-d24c-40b4-af11-124437ebc2c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGB90 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52612408-f337-4c95-bf1e-d17c2c6fb882

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/768 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2
- CACUL1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 20/644 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.545); catalogued as rs1201951219; called by muse, mutect2
- PKP3 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 42/886 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1176479626; called by muse, mutect2
- RAX2 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 19/541 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- TNXB | c.10954C>T p.Q3652* (on ENST00000647633; = p.Q3405* on NM_019105.8 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/432 reads (6%) | called by muse, mutect2
- RSPH9 | c.*1052T>G | 3'UTR (SNP) | VAF 9/151 reads (6%) | called by muse, mutect2
